Somatic mutation profile of tumor specimen C3L-00799-01 (aliquot CPT0025230009) from CPTAC case C3L-00799, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 41.5 years (15,150 days).
Specimen C3L-00799-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac6cc72e-e5af-4ff2-9db8-9d97f649c451.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00799-31 (Blood Derived Normal), aliquot CPT0029440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2b687378-c038-4b03-a9ee-8dd2bf2b7675

The open-access MAF lists 64 somatic variants for this specimen: 53 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Frame Shift Del 8, Nonsense Mutation 7, Silent 6, Splice Region 3, Intron 3, Frame Shift Ins 2, In Frame Del 1, 5'UTR 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 73/230 reads (32%) | catalogued as rs5030802, CM951268, CM984688, COSV56544079; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCNE1 | c.823T>G p.F275V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV52904705; called by muse, mutect2, varscan2
- CORO2B | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 21/401 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs377512463; called by muse, mutect2
- GALE | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV65720891; called by muse, mutect2, varscan2
- GOLGB1 | c.1112A>G p.K371R | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as rs142966732; called by muse, mutect2, varscan2
- IL12A | c.421-4C>A | Splice Region (SNP) | VAF 49/218 reads (22%) | catalogued as rs761130017; called by muse, varscan2
- LGI4 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.027); catalogued as rs767304375; called by muse, mutect2, varscan2
- MFSD2A | c.1322_1324del p.F441del (on ENST00000372809 / NM_001136493.3; = p.F428del on NM_032793.5 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 62/314 reads (20%) | catalogued as rs1445041219; called by pindel, varscan2
- MUC5AC | c.16088C>T p.A5363V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.864); catalogued as rs765361615; called by muse, mutect2, varscan2
- RASIP1 | c.1847A>T p.E616V | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99711251; called by muse, mutect2, varscan2
- SETD1B | c.1520T>C p.L507P | Missense Mutation (SNP) | VAF 69/311 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57350311; called by muse, mutect2, varscan2
- STIP1 | c.1560-5T>C | Splice Region (SNP) | VAF 46/213 reads (22%) | catalogued as rs761941889; called by muse, mutect2, varscan2
- TDP2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1562152158; called by muse, mutect2, varscan2
- AASDH | c.3294del p.K1098Nfs*10 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- AKAP6 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- B3GNT6 | c.541G>T p.E181* | Nonsense Mutation (SNP) | VAF 36/147 reads (24%) | called by muse, mutect2, varscan2
- CDH23 | c.1499G>T p.S500I | Missense Mutation (SNP) | VAF 41/186 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CEP350 | c.7228C>T p.Q2410* | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- CLPB | c.2053_2066del p.K685Sfs*12 | Frame Shift Del (DEL) | VAF 31/142 reads (22%) | called by mutect2, pindel, varscan2
- COQ9 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 76/381 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOK7 | c.862T>A p.S288T | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FAT3 | c.729C>A p.N243K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXN4 | c.1246A>T p.T416S | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GAB4 | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- HIVEP2 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 60/265 reads (23%) | called by muse, mutect2, varscan2
- HSPA8 | c.710T>C p.M237T | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- KIAA1522 | c.2407_2408insT p.G803Vfs*3 (on ENST00000373480 / NM_001198972.2; = p.G862Vfs*3 on NM_020888.3) | Frame Shift Ins (INS) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- KRT74 | c.701T>A p.I234N | Missense Mutation (SNP) | VAF 86/335 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LONP1 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 26/216 reads (12%) | called by muse, mutect2, varscan2
- MAP3K13 | c.421G>C p.V141L | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2
- MAP3K5 | c.1132A>T p.M378L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- MVP | c.2075del p.K692Rfs*21 | Frame Shift Del (DEL) | VAF 41/243 reads (17%) | called by mutect2, pindel, varscan2
- N4BP2 | c.3310T>A p.L1104I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NOTCH2 | c.4550A>G p.H1517R | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NSDHL | c.824del p.F275Sfs*9 | Frame Shift Del (DEL) | VAF 59/147 reads (40%) | called by mutect2, pindel, varscan2
- NTM | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 34/170 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- PBRM1 | c.3683_3684del p.C1228Yfs*20 (on ENST00000296302 / NM_001366071.2; = p.C1203Yfs*20 on NM_018313.5) | Frame Shift Del (DEL) | VAF 17/54 reads (31%) | called by mutect2, pindel, varscan2
- PDHX | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 83/300 reads (28%) | called by muse, mutect2, varscan2
- PLA2G4A | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLR2C | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- PRH1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 45/258 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RAPGEF2 | c.2724_2725insT p.R909Sfs*30 | Frame Shift Ins (INS) | VAF 32/152 reads (21%) | called by mutect2, pindel, varscan2
- RPRD2 | c.1740_1747del p.S581Tfs*12 | Frame Shift Del (DEL) | VAF 27/238 reads (11%) | called by mutect2, pindel, varscan2
- SLC25A33 | c.151del p.Y51Ifs*15 | Frame Shift Del (DEL) | VAF 65/332 reads (20%) | called by mutect2, pindel, varscan2
- SLC35G5 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 66/319 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCD3 | c.939+1G>A p.X313_splice (on ENST00000262188 / NM_001003801.2; = p.X300_splice on NM_003078.4) | Splice Site (SNP) | VAF 99/392 reads (25%) | called by muse, mutect2, varscan2
- SYT14 | c.353A>G p.Q118R | Missense Mutation (SNP) | VAF 74/321 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TAF1L | c.3778G>A p.E1260K | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- USF2 | c.109+5del | Splice Region (DEL) | VAF 37/165 reads (22%) | called by mutect2, pindel, varscan2
- WBP1 | c.26del p.G9Afs*23 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- ZNF226 | c.1704C>A p.F568L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF544 | c.474G>T p.E158D | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, varscan2
- ZNF544 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- APOH | c.291T>C p.Y97= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs143248721; called by muse, mutect2, varscan2
- CDK5 | c.399A>G p.L133= | Silent (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- NELL2 | c.306T>C p.V102= | Silent (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- RNF123 | c.3657C>T p.I1219= | Silent (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- SIRT7 | c.45G>A p.E15= | Silent (SNP) | VAF 56/201 reads (28%) | called by muse, mutect2, varscan2
- TMEM252 | c.219G>A p.L73= | Silent (SNP) | VAF 62/166 reads (37%) | called by muse, mutect2, varscan2
- ERN1 | c.54+20G>C | Intron (SNP) | VAF 18/78 reads (23%) | called by muse, varscan2
- PDLIM3 | c.94-9008A>T | Intron (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- PMS2 | c.-29G>A | 5'UTR (SNP) | VAF 77/354 reads (22%) | catalogued as rs1057520893; ClinVar: likely benign; called by muse, mutect2, varscan2
- RN7SL495P | chr15:22611230 G>A | 5'Flank (SNP) | VAF 84/1218 reads (7%) | called by muse, mutect2
- TCF7L2 | c.552+49408_552+49412del | Intron (DEL) | VAF 19/70 reads (27%) | called by mutect2, pindel, varscan2
